Gene-level copy-number profile of tumor specimen TCGA-B0-4688-01A from TCGA case TCGA-B0-4688, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 46.0 years (16,804 days).
Specimen TCGA-B0-4688-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRC.c10f46a8-d781-4ed1-b393-ae696c15d700.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B0-4688-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/847e9fc2-3716-4bf1-bfb2-4ef372dbac6f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 4,842; copy number 2: 32,614; copy number 3: 17,012; copy number 4: 3,412; copy number 5: 960; copy number 6: 246; copy number 7: 173; copy number 8: 191; copy number 11: 20; copy number 13: 86; copy number 14: 142; copy number 15: 77; copy number 16: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-B0-4688-01): tumor purity 0.7, ploidy 2.43, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:14,680,604–15,330,282, 25 genes: VN1R74P, GTF2IP8, ANKRD30B, RNU6-1210P, AP006565.1, MIR3156-2, LINC01906, FGF7P1, AP005121.1, LINC01443, LINC01444, AP005121.2, AP005242.4, AP005242.2, AP005242.3, AP005242.1, AP005242.5, AP005901.2, AP005901.6, AP005901.5, AP005901.3, BNIP3P3, AP005901.4, AP005901.1, RNU6-721P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,843 genes in 38 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:141,636,583–144,870,953, 30 genes, copy number 13 (within-gene range 2–13): IL15, INPP4B, RPL5P13, LSM3P4, AC139720.2, AC139720.1, AC104596.1, AC104596.2, USP38, AC097658.2, Y_RNA, GAB1, MIR3139, AC097658.1, AC097658.3, RPSAP36, AC104685.1, SMARCA5-AS1, SMARCA5, AC139713.1, AC107223.1, GUSBP5, FREM3, AC104090.1, GYPE, AC093890.1, GYPB, AC093890.2, GYPA, AC098588.3.
- chr4:158,700,691–160,818,869, 18 genes, copy number 14: U3, PPID, FNIP2, RNU6-128P, C4orf45, SNORD39, PSME2P3, FABP5P12, Y_RNA, RAPGEF2, MIR3688-1, MIR3688-2, AC074344.1, AC074344.2, LINC02233, AC093853.1, LINC02477, RPS14P7.
- chr7:21,543,039–21,945,903, 2 genes, copy number 5 (within-gene range 3–5): DNAH11, CDCA7L.
- chr10:4,962,436–8,515,106, 87 genes, copy number 5–8 (broad region; genes not listed).
- chr10:13,643,706–14,462,142, 1 gene, copy number 6 (within-gene range 4–6): FRMD4A.
- chr10:14,074,284–16,817,463, 41 genes, copy number 5–6 (within-gene range 2–6): AL157896.1, AL139405.1, MIR4293, Metazoa_SRP, MIR1265, FAM107B, AL158168.1, RNA5SP302, RPSAP7, CDNF, AC069544.2, HSPA14, AC069544.1, SUV39H2, DCLRE1C, MEIG1, OR7E110P, OR7E26P, OR7E115P, DCLRE1CP1, OLAH, ACBD7, GAPDHP45, RPP38-DT, RPP38, NMT2, PPIAP30, AL590365.1, FAM171A1, AL607028.1, ITGA8, MINDY3, AL358033.1, FTLP19, RNU6-1075P, LINC02654, PTER, RNU2-18P, C1QL3, AL353576.1, RSU1.
- chr11:20,669,551–21,575,686, 1 gene, copy number 5 (within-gene range 3–5): NELL1.
- chr11:21,000,881–23,203,161, 22 genes, copy number 5: RNA5SP336, AC090857.1, AC090857.2, AC099730.1, RNA5SP337, AC130307.1, ANO5, AC116534.1, AC107882.1, AC107886.1, AC104009.1, SLC17A6, AC040936.1, LINC01495, AC055878.1, FANCF, GAS2, RNA5SP338, SVIP, AC006299.1, CCDC179, LINC02718.
- chr11:75,815,210–76,144,232, 1 gene, copy number 5 (within-gene range 4–5): UVRAG.
- chr11:75,911,204–77,126,155, 30 genes, copy number 5: PPP1R1AP1, AP003168.2, RNA5SP344, AP003168.1, AP002340.1, WNT11, AP000785.1, LINC02761, THAP12, GVQW3, Y_RNA, AP002360.1, EMSY, AP001189.2, LINC02757, AP001189.5, AP001189.3, AP001189.1, LRRC32, AP001189.4, GUCY2EP, AP003119.1, TSKU, AP003119.2, AP003119.3, ACER3, AP002498.1, B3GNT6, CAPN5, OMP.
- chr11:86,791,059–86,952,910, 1 gene, copy number 5 (within-gene range 3–5): PRSS23.
- chr11:86,892,214–91,383,289, 112 genes, copy number 5 (broad region; genes not listed).
- chr11:96,590,317–96,985,810, 1 gene, copy number 6 (within-gene range 4–6): AP003066.1.
- chr11:97,000,274–104,609,498, 80 genes, copy number 6–8 (within-gene range 3–8) (broad region; genes not listed).
- chr11:118,193,725–118,531,094, 17 genes, copy number 5: JAML, HSPE1P18, MPZL3, MPZL2, AP002800.1, CD3E, AP001582.1, CD3D, CD3G, UBE4A, AP001267.1, AP001267.5, ATP5MG, AP001267.4, AP001267.2, KMT2A, AP001267.3.
- chr12:389,273–23,251,499, 620 genes, copy number 5–7 (broad region; genes not listed).
- chr12:23,637,973–23,638,487, 1 gene, copy number 5: AC087260.1.
- chr12:31,244,440–31,959,316, 36 genes, copy number 5: AC024940.4, AC024940.2, MREGP1, AC024940.5, SINHCAF, AC024940.3, FLJ13224, LINC02387, U6, DENND5B, RNU6-618P, AC068792.1, AC022080.1, AC022080.2, Y_RNA, ANKRD49P2, DENND5B-AS1, RNU5F-4P, RPL31P50, AK4P3, AC068774.1, ETFBKMT, AMN1, STMN1P1, AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P, AC023050.2, AC023050.3, LINC02422, AC023050.4, AC023050.1, RPL12P32, AC023050.5.
- chr13:23,134,174–26,698,804, 84 genes, copy number 5–11 (broad region; genes not listed).
- chr13:35,697,487–36,442,870, 9 genes, copy number 16: LINC00445, DCLK1, SOHLH2, CCDC169-SOHLH2, CCDC169, RNU6-71P, SPART, SPART-AS1, CCNA1.
- chr13:44,799,503–46,897,076, 56 genes, copy number 13: LINC00330, NUFIP1, AL359706.1, GPALPP1, RN7SL49P, RN7SKP3, GTF2F2, RN7SKP4, AL138693.1, KCTD4, AL138963.2, TPT1, SNORA31B, SNORA31, AL138963.3, TPT1-AS1, AL138963.1, RCN1P2, SLC25A30, SLC25A30-AS1, PPIAP25, COG3, ERICH6B, RNA5SP27, TIMM9P3, COX4I1P2, LINC01055, AKR1B1P4, CBY2, Metazoa_SRP, SIAH3, ZC3H13, CPB2-AS1, CPB2, LCP1, RN7SL288P, LRRC63, RN7SKP5, ABITRAMP1, AL139801.1, LINC00563, RUBCNL, RNU2-6P, RNU6-68P, PPP1R2P4, LINC01198, AL138686.2, OR7E101P, AL138686.1, COX17P1, FKBP1AP3, LRCH1, AL359880.1, ESD, HTR2A, HTR2A-AS1.
- chr13:48,771,128–49,633,872, 18 genes, copy number 14: PSME2P2, AL161421.1, FNDC3A, RNU6-60P, RAD17P2, RNY3P2, COX7CP1, OGFOD1P1, MLNR, AL137000.1, CDADC1, CAB39L, SETDB2, SNRPGP14, PHF11, RCBTB1, AL135901.1, ARL11.
- chr13:101,452,593–101,720,856, 1 gene, copy number 6: ITGBL1.
- chr13:101,717,564–101,802,488, 3 genes, copy number 6: AL160153.1, RNU1-24P, HMGB3P7.
- chr13:107,531,171–107,933,503, 4 genes, copy number 6: MIR1267, FAM155A-IT1, AL359436.1, AL136964.1.
- chr14:27,258,717–37,172,606, 167 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr14:39,385,404–46,651,781, 60 genes, copy number 6–8: COILP1, FBXO33, AL049828.1, AL049828.2, AL390800.1, LINC02315, AL391516.1, AL356596.1, AL121821.3, AL121821.2, AL121821.1, LRFN5, FKBP1BP1, AL445074.1, AL442163.1, AL450442.1, AL442163.2, AL442163.3, YWHAQP1, AL163153.1, TUBBP3, HNRNPUP1, AL583809.1, KRT8P2, AL358913.1, ARHGAP16P, LINC02307, EIF4BP1, AL109766.1, YWHAZP1, AL161752.1, LINC02277, FSCB, AL356022.1, LINC02302, DOCK11P1, AL049870.2, AL049870.1, RRAGAP1, C14orf28, AL049870.3, KLHL28, TOGARAM1, AL121809.2, AL121809.1, PRPF39, SNORD58, SNORD127, FKBP3, FANCM, MIS18BP1, RNU6-552P, DNAJC19P9, AL162632.3, AL162632.1, AL162632.2, AL139354.1, LINC02303, LINC00871, RPL10L.
- chr14:48,394,815–49,077,505, 5 genes, copy number 8 (within-gene range 3–8): AL358335.2, AL358335.1, RPL18P1, AL512360.1, AL110505.1.
- chr14:51,989,514–53,157,528, 27 genes, copy number 6: RTRAF, NID2, LINC02319, COX5AP2, AL118557.1, PTGDR, AL365475.1, PTGER2, TXNDC16, GPR137C, ERO1A, AL133453.1, PSMC6, STYX, GNPNAT1, AL139317.3, AL139317.5, AL139317.1, AL139317.2, FERMT2, AL139317.4, AL352979.4, AL352979.1, AL352979.3, DDHD1, AL352979.2, AL356020.1.
- chr14:53,364,146–53,392,048, 1 gene, copy number 6: AL365295.2.
- chr14:60,179,382–60,248,765, 3 genes, copy number 6: PSMA3P1, RPL17P2, AL157756.1.
- chr14:63,761,899–64,226,433, 1 gene, copy number 6 (within-gene range 3–6): SYNE2.
- chr14:64,084,232–64,944,591, 23 genes, copy number 6 (within-gene range 3–6): ESR2, MIR548H1, AL161756.1, TEX21P, AL161756.3, AL161756.2, MTHFD1, AL122035.1, AL122035.2, ZBTB25, AKAP5, ZBTB1, AL049869.2, AL049869.3, HSPA2, PPP1R36, AL049869.1, NUP50P1, PLEKHG3, SPTB, MIR7855, RPPH1-2P, CHURC1.
- chr14:66,411,704–69,244,020, 62 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr14:69,854,131–73,790,285, 93 genes, copy number 5–15 (within-gene range 3–15) (broad region; genes not listed).
- chr14:74,763,316–78,060,278, 103 genes, copy number 14 (within-gene range 3–14) (broad region; genes not listed).
- chr14:78,177,803–78,753,878, 6 genes, copy number 6–14: RNA5SP388, RPS26P48, AF099810.1, AC009396.2, AC009396.3, AC009396.1.
- chr14:92,703,807–93,333,092, 16 genes, copy number 5 (within-gene range 3–5): LGMN, GOLGA5, LINC02833, LINC02287, CHGA, ITPK1, ITPK1-AS1, CYB5AP3, MOAP1, TMEM251, AL110118.1, GON7, UBR7, AL132838.1, BTBD7, AL132838.2.

Autosomal genes at a single copy (total copy number 1): 4,378. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
